Somatic mutation profile of tumor specimen TCGA-BA-6868-01B (aliquot TCGA-BA-6868-01B-12D-1912-08) from TCGA case TCGA-BA-6868, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 53.7 years (19,608 days).
Specimen TCGA-BA-6868-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b37ee49a-3459-4726-b21d-b3139a755db0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-6868-10A (Blood Derived Normal), aliquot TCGA-BA-6868-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aa3fa51-3c68-4aab-88f2-ac2083d8ea3e

The open-access MAF lists 168 somatic variants for this specimen: 128 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 37, Nonsense Mutation 10, Frame Shift Ins 3, Frame Shift Del 3, 3'UTR 2, Splice Region 2, In Frame Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 29/43 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC12 | c.2786A>C p.N929T | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.115); catalogued as COSV60918179; called by muse, mutect2
- ABCG8 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM021483, COSV99700146; called by muse, mutect2, varscan2
- AC093827.5 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.509); catalogued as rs779308489, COSV55745293, COSV55745663; called by muse, mutect2, varscan2
- ACIN1 | c.2284A>G p.I762V | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV99400160; called by muse, mutect2, varscan2
- ADCY9 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99570644; called by muse, mutect2, varscan2
- ADGRG2 | c.1875G>T p.M625I (on ENST00000379869 / NM_001079858.3; = p.M622I on NM_005756.4) | Missense Mutation (SNP) | VAF 92/127 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV100492541; called by muse, mutect2, varscan2
- AEN | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100237582; called by muse, mutect2, varscan2
- AHCY | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV99464414; called by muse, mutect2, varscan2
- AHNAK2 | c.6260A>G p.K2087R | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs1415416564, COSV100318610; called by muse, mutect2, varscan2
- ARAP1 | c.1815C>G p.F605L (on ENST00000393609 / NM_001040118.2; = p.F360L on NM_015242.4) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV100502112; called by muse, mutect2
- ATP1A1 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99814690; called by muse, mutect2, varscan2
- BPTF | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV100075742, COSV58834434; called by muse, mutect2, varscan2
- CATSPER1 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as COSV100376187; called by muse, mutect2, varscan2
- CCT2 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.635); catalogued as COSV100167775; called by muse, mutect2, varscan2
- CDC25B | c.991C>G p.P331A (on ENST00000245960 / NM_021873.3; = p.P317A on NM_004358.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV99848276; called by muse, mutect2
- CDK13 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371566821; called by muse, mutect2, varscan2
- CLK3 | c.1366_1368del p.E456del (on ENST00000395066 / NM_001130028.1; = p.E308del on NM_003992.4) | In Frame Del (DEL) | VAF 44/94 reads (47%) | catalogued as rs1171107440; called by pindel, varscan2
- CMYA5 | c.8540C>G p.T2847R | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV101484282; called by muse, mutect2, varscan2
- CNTN5 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV54279470; called by muse, mutect2
- COL11A1 | c.1643C>A p.S548* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62178371, COSV62180680; called by muse, mutect2, varscan2
- COL4A4 | c.2087C>A p.A696D | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.335); catalogued as rs1394976876, COSV100307497; called by muse, mutect2, varscan2
- CTU2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99966452; called by muse, mutect2, varscan2
- CYP2F1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs376080668; called by muse, mutect2, varscan2
- DENND1A | c.529G>C p.V177L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV101010767; called by muse, mutect2, varscan2
- DIS3L2 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99807046; called by muse, mutect2, varscan2
- DNAH14 | c.609-1G>C p.X203_splice (on ENST00000445597; = p.X26_splice on NM_144989.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 29/92 reads (32%) | catalogued as COSV100835953; called by muse, mutect2, varscan2
- DOCK7 | c.2188A>G p.I730V | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747262593, COSV99225607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP2 | c.1453C>T p.Q485* (on ENST00000075322 / NM_001040092.3; = p.Q537* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 92/364 reads (25%) | catalogued as COSV99309117; called by muse, mutect2, varscan2
- EPHA6 | c.2179A>T p.I727F (on ENST00000389672 / NM_001080448.3; = p.I119F on NM_173655.4) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101065073; called by muse, mutect2, varscan2
- FAM135B | c.3313G>C p.E1105Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.09); catalogued as COSV52714522, COSV99426504; called by muse, mutect2, varscan2
- FASTKD1 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV101328535; called by muse, mutect2, varscan2
- FBXW7 | c.1505C>T p.A502V (on ENST00000281708 / NM_001349798.2; = p.A422V on NM_018315.5) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV99659919; called by muse, mutect2, varscan2
- FGF5 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100428020; called by muse, mutect2, varscan2
- FHOD3 | c.2299G>C p.E767Q (on ENST00000359247 / NM_001281739.3; = p.E784Q on NM_025135.5) | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV57178279, COSV99942319; called by muse, mutect2, varscan2
- FUT5 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99398939; called by muse, mutect2, varscan2
- GORAB | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV100883777; called by muse, mutect2, varscan2
- GPRC5B | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs147744945; called by muse, mutect2, varscan2
- GTF2H1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56380393; called by muse, mutect2, varscan2
- HEXIM1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100203559; called by muse, mutect2, varscan2
- HFE | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.161); catalogued as COSV100352657; called by muse, mutect2, varscan2
- HNRNPDL | c.284T>C p.I95T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99787200; called by muse, mutect2, varscan2
- HPX | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as COSV99793466; called by muse, mutect2, varscan2
- IGHV2-5 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs148245067; called by muse, mutect2, varscan2
- INPP4B | c.1341A>C p.L447F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99526123; called by muse, mutect2, varscan2
- IRS4 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 236/324 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV100929668; called by muse, mutect2, varscan2
- JAK3 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101512996; called by muse, mutect2, varscan2
- JPH1 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV100646735; called by muse, mutect2, varscan2
- KCNB2 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101578931; called by muse, mutect2, varscan2
- KCNK13 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs150186575, COSV99965875; called by muse, mutect2, varscan2
- KIAA0100 | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV101197381; called by muse, mutect2, varscan2
- KLHDC8A | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 48/103 reads (47%) | catalogued as rs757614022, COSV100903863, COSV65679077; called by muse, mutect2, varscan2
- LCOR | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.549); catalogued as rs1472548543, COSV100603804; called by muse, mutect2, varscan2
- LRP1B | c.10840A>T p.N3614Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101259550; called by muse, mutect2, varscan2
- LRP2 | c.2033A>G p.H678R | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as COSV99789822; called by muse, mutect2, varscan2
- LRP4 | c.3067C>G p.P1023A | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV101066801; called by muse, mutect2, varscan2
- MAMSTR | c.1201G>C p.D401H (on ENST00000318083 / NM_001130915.2; = p.D298H on NM_182574.2) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100540631; called by muse, mutect2, varscan2
- MDN1 | c.8871A>T p.R2957S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV101021693; called by muse, mutect2, varscan2
- MIOX | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs769242335, COSV53312893; called by muse, mutect2, varscan2
- MRPL41 | c.275T>G p.F92C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99481244; called by muse, mutect2, varscan2
- MRPS10 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99273647; called by muse, mutect2, varscan2
- MRPS9 | c.476A>T p.Y159F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV99306247, COSV99306295; called by muse, mutect2, varscan2
- MXRA5 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV54249598; called by muse, mutect2, varscan2
- MYO18B | c.7376G>C p.G2459A | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV100124724; called by muse, mutect2, varscan2
- NAPRT | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.904); catalogued as rs1216915367, COSV52787277; called by muse, mutect2, varscan2
- NCOR2 | c.6002C>G p.P2001R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV100657750; called by muse, mutect2
- NHLRC3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV101099026; called by muse, mutect2, varscan2
- NOTCH1 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53050614, COSV53059882; called by muse, mutect2, varscan2
- NOVA1 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV99946841; called by muse, mutect2, varscan2
- OGG1 | c.897G>A p.L299= | Splice Region (SNP) | VAF 28/36 reads (78%) | catalogued as rs774936668, COSV99844892; called by muse, mutect2, varscan2
- OR2G6 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100598292, COSV100598355, COSV58574511; called by muse, mutect2, varscan2
- OR5W2 | c.573T>A p.D191E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV100747726, COSV60617215; called by muse, mutect2, varscan2
- PCIF1 | c.802A>G p.M268V | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100976110; called by muse, mutect2, varscan2
- PCNT | c.4352G>A p.R1451H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs200697914, COSV100855920, COSV64026257; called by muse, mutect2, varscan2
- PDGFD | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 28/428 reads (7%) | catalogued as rs767074927, COSV100161481, COSV56369436; called by muse, mutect2
- PIK3C3 | c.2255C>G p.T752R | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV100011450; called by muse, mutect2, varscan2
- PIK3R4 | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV100768559; called by muse, mutect2, varscan2
- PKHD1L1 | c.1377C>G p.Y459* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV101006671; called by muse, mutect2, varscan2
- POLK | c.408G>T p.L136= | Splice Region (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99606328; called by muse, mutect2, varscan2
- POLQ | c.5948A>T p.E1983V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99952717; called by muse, varscan2
- PPM1D | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as rs1276428173, COSV100011092; called by muse, mutect2, varscan2
- PPP2R3A | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53870762, COSV99387945; called by muse, mutect2
- PRDM2 | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99342490; called by muse, mutect2, varscan2
- RASL12 | c.750C>A p.S250R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99585141; called by muse, mutect2, varscan2
- RFFL | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99265492; called by muse, mutect2, varscan2
- RGL2 | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101442510; called by muse, mutect2, varscan2
- RGMB | c.1069C>G p.Q357E (on ENST00000513185 / NM_001366508.1; = p.Q398E on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV100374996; called by muse, mutect2, varscan2
- RIC1 | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV52605101, COSV99317822; called by muse, mutect2, varscan2
- RSPH4A | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.07); catalogued as COSV99994267; called by muse, mutect2, varscan2
- RUNX1T1 | c.1418G>A p.R473Q (on ENST00000265814 / NM_001198628.1; = p.R446Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs774408067, COSV56146644; called by muse, mutect2, varscan2
- SEZ6L2 | c.701G>A p.G234D (on ENST00000308713 / NM_001114099.3; = p.G164D on NM_012410.4) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV100435729; called by muse, mutect2, varscan2
- SH2D7 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs746232029, COSV100174799; called by muse, mutect2, varscan2
- SHANK2 | c.2929T>G p.F977V | Missense Mutation (SNP) | VAF 56/924 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.523); catalogued as COSV99575604; called by muse, mutect2
- SLC45A2 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs888610793, COSV99673039; called by muse, mutect2, varscan2
- SLC6A15 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV99881375; called by muse, mutect2
- SOX5 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as COSV100507746; called by muse, mutect2, varscan2
- SPATA18 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs758283137, COSV54645498, COSV99731064; called by muse, mutect2, varscan2
- SPHKAP | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100764433, COSV60891288; called by muse, mutect2, varscan2
- SPINDOC | c.1099T>G p.S367A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV99588762; called by muse, mutect2, varscan2
- STOX2 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100409080; called by muse, mutect2, varscan2
- SYNE2 | c.6613C>T p.Q2205* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100648322; called by muse, mutect2, varscan2
- TAF1D | c.30C>G p.D10E | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV100127043; called by muse, mutect2, varscan2
- TAOK3 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | catalogued as COSV101183687; called by muse, mutect2, varscan2
- TDRD6 | c.2221A>G p.K741E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs1362358321, COSV100288140; called by muse, mutect2, varscan2
- TFAP2B | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.288); catalogued as rs1040820081, COSV99540683; called by muse, mutect2, varscan2
- TFAP4 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99200089; called by muse, mutect2, varscan2
- TLR3 | c.2696C>G p.S899C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1431024449, COSV99711145; called by muse, mutect2, varscan2
- TMEM117 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99863407; called by muse, mutect2, varscan2
- TMEM219 | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99666171; called by muse, mutect2, varscan2
- TNRC6A | c.671A>T p.N224I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV100170374; called by muse, mutect2, varscan2
- TPTE | c.961G>T p.E321* (on ENST00000618007 / NM_199261.4; = p.E303* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 56/404 reads (14%) | catalogued as rs1463937346; called by muse, mutect2, varscan2
- TRHDE | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV99671999; called by muse, mutect2, varscan2
- TSKU | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV100289927; called by muse, mutect2, varscan2
- VTN | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99879797; called by muse, mutect2, varscan2
- WASHC4 | c.3154A>G p.M1052V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV100162678; called by muse, mutect2, varscan2
- WDSUB1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63067269; called by muse, mutect2, varscan2
- XRN1 | c.4259A>G p.H1420R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs767995337, COSV99378713; called by muse, mutect2, varscan2
- ZAN | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.25); catalogued as rs988782745, COSV100770129; called by muse, mutect2, varscan2
- ZFP42 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100479107; called by muse, mutect2, varscan2
- ZNF280B | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100840417; called by muse, mutect2, varscan2
- ZNF99 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as rs768895231, COSV101233917; called by muse, mutect2, varscan2
- DDX43 | c.252_256del p.R85Wfs*47 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel*
- HEATR5A | c.2420dup p.L808Ifs*29 | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- LAMP5 | c.128_145del p.P43_V49delinsL | In Frame Del (DEL) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- LRP1B | c.11038del p.L3680Ffs*76 | Frame Shift Del (DEL) | VAF 38/153 reads (25%) | called by mutect2, pindel, varscan2
- PCSK7 | c.1655dup p.M552Ifs*20 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- PLEKHG1 | c.4133_4134del p.C1378Sfs*16 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by pindel, varscan2
- ZMYM6 | c.3924dup p.A1309Cfs*37 | Frame Shift Ins (INS) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- ARAP3 | c.360C>T p.L120= | Silent (SNP) | VAF 108/150 reads (72%) | catalogued as rs201975820; called by muse, mutect2, varscan2
- ARID1B | c.4740C>T p.T1580= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as rs745670548, COSV51651395; called by muse, mutect2, varscan2
- CCDC57 | c.459A>G p.K153= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1286823245, COSV101052047; called by muse, mutect2
- CEBPZ | c.489A>G p.K163= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV99135735; called by muse, mutect2, varscan2
- CLEC18B | c.52C>T p.L18= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs141907838; called by muse, mutect2, varscan2
- DHX38 | c.3438C>T p.P1146= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99194518; called by muse, mutect2, varscan2
- DSCAML1 | c.1767C>T p.I589= (on ENST00000321322; = p.I529= on NM_020693.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1427398045, COSV100356861; called by muse, mutect2, varscan2
- FBP1 | c.615G>A p.K205= | Silent (SNP) | VAF 66/96 reads (69%) | catalogued as COSV100941326; called by mutect2, varscan2
- FRMPD4 | c.558C>T p.I186= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV101043782; called by muse, mutect2, varscan2
- IMPDH2 | c.732G>A p.L244= | Silent (SNP) | VAF 121/164 reads (74%) | catalogued as COSV100455152; called by muse, mutect2, varscan2
- KIFC2 | c.2352G>T p.P784= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100023946, COSV56760871; called by muse, mutect2, varscan2
- MAML3 | c.1443C>T p.L481= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1326401591, COSV100505406; called by muse, mutect2, varscan2
- MYO18B | c.180C>T p.V60= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs755446258, COSV100124721; called by muse, mutect2, varscan2
- OR2G3 | c.243C>G p.T81= | Silent (SNP) | VAF 128/332 reads (39%) | catalogued as COSV100180709, COSV60681528; called by muse, mutect2, varscan2
- OR51G1 | c.15T>G p.L5= | Silent (SNP) | VAF 32/46 reads (70%) | catalogued as COSV100429359, COSV58969475, COSV99062544; called by muse, mutect2, varscan2
- P2RY10 | c.639C>T p.I213= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs1270835675, COSV50680353; called by muse, mutect2, varscan2
- PCDHB10 | c.2382C>T p.S794= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99504838; called by muse, mutect2, varscan2
- PCDHB11 | c.1428A>C p.T476= | Silent (SNP) | VAF 45/263 reads (17%) | catalogued as COSV100697131; called by muse, mutect2, varscan2
- PCDHGA2 | c.1428C>A p.A476= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV99544414; called by muse, mutect2, varscan2
- PRDM8 | c.915C>T p.I305= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100325304, COSV60204004; called by muse, mutect2, varscan2
- PRKDC | c.10968C>T p.L3656= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100042286; called by muse, mutect2, varscan2
- PRSS58 | c.237G>T p.L79= | Silent (SNP) | VAF 38/55 reads (69%) | catalogued as COSV101616155, COSV73488757; called by muse, mutect2, varscan2
- RAVER1 | c.765C>T p.C255= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs751621218, COSV53345166; called by muse, mutect2, varscan2
- RELA | c.804C>T p.V268= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100425910; called by muse, mutect2, varscan2
- SH3BP5L | c.657C>T p.I219= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs759676523, COSV63539441; called by muse, mutect2, varscan2
- SLC2A11 | c.870C>T p.D290= (on ENST00000345044 / NM_001024938.4; = p.D297= on NM_030807.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99741742; called by muse, mutect2
- STX6 | c.441C>G p.L147= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as COSV99275989; called by muse, mutect2, varscan2
- TANC1 | c.3033G>T p.R1011= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99714925; called by muse, mutect2, varscan2
- TECTA | c.2868T>G p.S956= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99881154; called by muse, mutect2, varscan2
- TLR3 | c.1773C>T p.I591= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs757517639, COSV57169477; called by muse, mutect2, varscan2
- TRPM1 | c.4101A>G p.R1367= | Silent (SNP) | VAF 67/136 reads (49%) | catalogued as COSV99856458; called by muse, mutect2, varscan2
- TTC27 | c.1191A>G p.K397= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV100513433; called by muse, mutect2, varscan2
- VWA8 | c.2973G>A p.P991= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as rs140209374; called by muse, mutect2, varscan2
- WWP1 | c.702A>G p.A234= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99616967; called by muse, mutect2, varscan2
- ZFHX4 | c.5754T>C p.F1918= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV50489796, COSV51487782, COSV99266389; called by muse, mutect2, varscan2
- ZNF446 | c.225G>C p.L75= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99543442; called by muse, mutect2, varscan2
- ZNF91 | c.1584A>G p.R528= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100323334; called by muse, varscan2
- AARS1 | c.*2_*28del | 3'UTR (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel
- KIF1B | c.2115+6873C>T | Intron (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99823996; called by muse, mutect2, varscan2
- RAB4A | c.*1382A>G | 3'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100796975; called by muse, mutect2, varscan2
